Somatic mutation profile of tumor specimen TARGET-10-PASYIS-09A (aliquot TARGET-10-PASYIS-09A-01D) from TARGET case TARGET-10-PASYIS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.0 years (2,937 days).
Specimen TARGET-10-PASYIS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4f74349-221c-4ec7-838e-9007ffba4d0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASYIS-10A (Blood Derived Normal), aliquot TARGET-10-PASYIS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d35e86f-a3a1-4d05-8d2a-8039fafde6f6

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, 3'UTR 1, In Frame Ins 1, 5'UTR 1, Frame Shift Ins 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC57 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.048); catalogued as rs552789709, COSV58937262; called by muse, varscan2
- CDH20 | c.2260G>A p.G754S | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV53018027; called by muse, varscan2
- CTCF | c.888_889insT p.H297Sfs*18 | Frame Shift Ins (INS) | VAF 45/127 reads (35%) | catalogued as COSV50519279; called by mutect2, pindel, varscan2
- GABBR2 | c.1480A>T p.I494F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV52319364; called by muse, mutect2
- IRF5 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750886286, COSV50861545; called by muse, mutect2, varscan2
- MAP3K10 | c.1087T>C p.S363P | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53425313; called by muse, mutect2, varscan2
- NDST4 | c.2545C>G p.L849V | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52137250, COSV99997038; called by muse, mutect2, varscan2
- NEK10 | c.1038T>G p.N346K | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.462); catalogued as COSV58289534; called by muse, mutect2, varscan2
- NLRP6 | c.2170A>G p.T724A | Missense Mutation (SNP) | VAF 99/205 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV56461934; called by muse, varscan2
- NOTCH1 | c.5078T>C p.F1693S | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53057652; called by muse, mutect2, varscan2
- NOTCH1 | c.4721T>A p.L1574Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53024760, COSV53072929; called by muse, mutect2
- SLC9A3 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as rs374864121; called by muse, mutect2, varscan2
- FLT3 | c.1146_1147insCCTACC p.T382_W383insPT | In Frame Ins (INS) | VAF 38/204 reads (19%) | called by mutect2, pindel*, varscan2
- PHF6 | c.100del p.S34Lfs*47 | Frame Shift Del (DEL) | VAF 27/38 reads (71%) | called by pindel*, varscan2
- DACT2 | c.2118C>T p.G706= | Silent (SNP) | VAF 63/125 reads (50%) | catalogued as rs1208962474, COSV64693929, COSV64694064; called by muse, mutect2, varscan2
- LILRB4 | c.1239C>T p.Y413= (on ENST00000391733 / NM_001278428.3; = p.Y412= on NM_001278426.3) | Silent (SNP) | VAF 32/106 reads (30%) | catalogued as rs191773308; called by muse, mutect2, varscan2
- SLC9A5 | c.624C>T p.G208= | Silent (SNP) | VAF 40/153 reads (26%) | catalogued as rs780350480, COSV55361987; called by muse, mutect2, varscan2
- SZT2 | c.9339C>T p.Y3113= (on ENST00000634258 / NM_001365999.1; = p.Y3056= on NM_015284.4) | Silent (SNP) | VAF 35/172 reads (20%) | catalogued as rs567417929; called by muse, mutect2, varscan2
- PKD1L2 | chr16:81139533 C>T | 5'Flank (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- TMCO1 | c.*33dup | 3'UTR (INS) | VAF 29/125 reads (23%) | called by mutect2, pindel, varscan2
- WARS1 | c.-64G>A | 5'UTR (SNP) | VAF 21/43 reads (49%) | catalogued as rs978097192; called by muse, mutect2, varscan2
